CCG case CUPP-B7A4 — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d64f8cbc-45d3-4805-bb51-26b29efa439a

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 7,693 days (21.1 years); Year of death: 2020; Cause of death: Not Cancer Related; Country of birth: Mexico.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C80.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Year of diagnosis: 1999; Tumor grade: G3; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: First-Line Therapy.
   Recorded as not given: first-line therapy Hormone Therapy; first-line therapy Immunotherapy (Including Vaccines); first-line therapy Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 7,693 days (21.1 years); Year of follow up: 2020.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B7A4-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B7A4-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 31; Percent tumor nuclei: 28; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 69; Percent lymphocyte infiltration: 69; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
